Surgical pathology report (de-identified scan), TCGA case TCGA-90-A4EE, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-90-A4EE-01A (Primary Tumor).

[page 1 of 4]
Operative Procedure:
Left thoracotomy

Pre-Operative Diagnosis:
As below

Post-Operative Diagnosis:
As below

Specimen Received:

- A: Inferior pulmonary ligament
- B: Retroesophageal lymph node
- C: Hilar lymph node
- D: Subcarinal lymph node
- E: Paratracheal lymph node
- F: Right lung; stitch on bronchus, check proximal margin (FS)

Final Pathologic Diagnosis:

- A. Lymph node, inferior pulmonary ligament, excision:
One lymph node, negative for malignancy (0/1).
- B. Lymph node, retroesophageal, excision:
One lymph node, negative for malignancy (0/1).
- C. Lymph node, hilar, excision:
One lymph node, negative for malignancy (0/1).
- D. Lymph node, subcarinal, excision:
Two lymph nodes, negative for malignancy (0/2).
- E. Lymph node, paratracheal, excision:
Three lymph nodes, negative for malignancy (0/3).
Hyalinized granuloma.
- F. Lung, right, pneumonectomy:
Poorly differentiated squamous cell carcinoma (4.8 cm in greatest dimension).
Frozen section diagnosis confirmed.
See Synoptic Report and Note below.

Synoptic Report

Specimen: Lung
Procedure: Thoracotomy
Specimen laterality: Right
Tumor site: bronchial

ICB-0-3

Carcinoma, squamous cell, NOS 8070/3

Site: lung, bronchus, NOS C34.9

hw
9/2/12

[page 2 of 4]
Specimen integrity: Intact
Tumor size: 4.8 cm (greatest dimension)
Tumor focality: Unifocal
Tumor histologic type: Squamous cell carcinoma
Tumor grade: Poorly differentiated
Visceral pleura invasion: Present
Tumor extension: Involves the visceral pleura

Margins:
Bronchial margin: Uninvolved by invasive carcinoma
Vascular margin: Uninvolved by invasive carcinoma
Parenchymal margin: Not applicable
Parietal pleural margin: Not applicable
Chest wall margin: Not applicable
Other attached tissue margin: Not applicable

If all margins uninvolved by invasive carcinoma:
Distance of invasive carcinoma from closest margin: 5 mm
Specify margin: Bronchial margin

Treatment effect: Not applicable
Lymph-vascular invasion: Present

Pathologic Staging (pTNM):

TNM Descriptors: None known

Primary tumor (pT): pT2a

Regional lymph nodes (pN): pN1

Number examined: 10

Number involved: 1

If lymph node(s) involved, specify involved nodal station(s):

Peribronchial

Distant metastasis (pM): pMx cannot be assessed

Additional pathologic findings: Respiratory bronchiolitis
Emphysematous changes
Bronchiole dilatation
Hyalinized and calcified granuloma

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Intraoperative Consult Diagnosis:

FSF: Right lung, stitch on bronchus check bronchial margin:
No tumor identified at margin.

FS TAT: 25 mins.

Gross Description:

The specimen is received in six separate parts, all labeled with the patient

[page 3 of 4]
name. Part F is received for frozen section. The remaining specimens are received in a single formalin filled container.

Part A is additionally labeled, "inferior pulmonary ligament" and consists of a red-brown ragged soft tissue that is 1.8 x 0.9 x 0.3 cm. The specimen is submitted in toto in cassette A.

Part B is additionally labeled, "retroesophageal lymph node" and consists of a pink to white-tan lymph node that is 2.0 x 1.3 x 0.7 cm and is bisected and submitted entirely in cassettes B1-2.

Part C is additionally labeled, "hilar lymph node" and consists of a red to purple-brown ragged soft tissue that is 1.0 x 0.4 x 0.2 cm and submitted in toto in cassette C.

Part D is additionally labeled, "subcarinal lymph node" and consists of two red-tan to red-brown irregular ragged soft tissues that are 4.5 x 2.3 x 0.6 cm and 4.6 x 1.2 x 0.8 cm. The larger fragment has a gray-purple to yellow-tan firm cut surface. Representative sections are submitted in cassettes D1 through 3. The smaller fragment has a gray-purple cut surface with an apparent vessel coursing through the middle. Representative sections are submitted in cassette D4. Additional sections of both are submitted in cassettes D5 through D7.

Part E is additionally labeled, "paratracheal lymph node" and consists of an irregular yellow-tan to red-brown soft tissue that is 6.6 x 2.1 x 1.3 cm. Three probable lymph nodes are identified that are 3.0, 1.6 and 1.0 cm. The largest node has a gray-purple to white-tan cut surface and is entirely submitted in cassettes E1 through E3 and E5 through E6. The remaining smaller nodes are submitted entirely in cassette E4.

Part F is additionally labeled, "right lung" and is received with a stitch marking the bronchus. The bronchial margin is removed for frozen section diagnosis. The remaining specimen consists of a right lung that is 17 x 17.5 x 4.0 cm. The pleural surface is gray-tan and smooth. The lower lobes are more firm to palpation. Sectioning of the lower lobe reveals multiple yellow-tan mucus and purulent fluid and dilated bronchioles. Sectioning near the bronchus reveals a white-tan firm lesion that is 4.8 x 3.9 x 3.4 cm. There are areas near the edge of the mass that appear degenerated. The mass appears to bulge into the bronchial lumen but does not appear to invade through the mucosa. The bronchial margin is approximately 5 mm from the lesion. The nearest vascular margins are 0.8 and 1.5 cm. The lesion abuts the pleural surface but does not grossly appear to invade through the pleural surface. The remaining lung parenchyma of the upper lobe is red-brown and spongy. There are multiple calcified lymph nodes surrounding the bronchus. Representative sections are submitted as follows:

- F1 residual frozen tissue from the bronchial margin;
- F2-3 tumor to show abutting bronchus;
- F4-5 tumor to include nearest pleura;
- F6 tumor to adjacent lung parenchyma;
- F7 representative section of consolidated lower lobe;

[page 4 of 4]
- F8 representative section of normal lung parenchyma from the upper lobe;
- F9 calcified lymph node following decalcification;
- F10 lymph node;
- F11 vascular margin.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken:

Gender: M

Duplicate/Synchronous Primarily Noted		1

Source: NCI Genomic Data Commons file 7bccb3da-832e-453f-bb7e-315c1f95bcb7 (TCGA-90-A4EE.254583DA-8861-45AB-A261-7EFA42C20A98.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).